Somatic mutation profile of tumor specimen 0DNYO1 from CCDI case PBCCCJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 6.7 years (2,434 days).
Specimen 0DNYO1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9453e598-b051-4dfd-9dc9-325bee105d16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNYNK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28476978-bca4-499e-8984-14e4782f9710

The open-access MAF lists 28 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Intron 3, Splice Region 2, 3'UTR 2, Frame Shift Del 1, Splice Site 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUBN | c.5983G>T p.G1995C | Missense Mutation (SNP) | VAF 198/478 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64715880; called by muse, mutect2, varscan2
- MMP20 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 257/630 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs759157092; called by muse, mutect2, varscan2
- SLITRK4 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 248/589 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1306554005, COSV62024242; called by muse, mutect2, varscan2
- TMEM229A | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV101492289; called by muse, mutect2, varscan2
- UQCRFS1 | c.61G>C p.G21R | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1386524592; called by mutect2, varscan2
- ADGRV1 | c.14420A>G p.H4807R | Missense Mutation (SNP) | VAF 270/658 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD31 | c.551C>A p.P184Q | Missense Mutation (SNP) | VAF 256/713 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- DNAH8 | c.7207+1G>T p.X2403_splice | Splice Site (SNP) | VAF 44/824 reads (5%) | called by muse, mutect2
- EHMT2 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 20/500 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); called by muse, mutect2
- GAB1 | c.2045A>C p.Q682P | Missense Mutation (SNP) | VAF 112/549 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- HNRNPLL | c.630T>C p.V210= | Splice Region (SNP) | VAF 188/436 reads (43%) | called by muse, mutect2, varscan2
- NDNF | c.1585del p.T529Qfs*20 | Frame Shift Del (DEL) | VAF 208/482 reads (43%) | called by mutect2, varscan2
- OBI1 | c.101A>G p.N34S | Missense Mutation (SNP) | VAF 272/768 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PLXNA3 | c.5157-8G>T | Splice Region (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- TRPC4 | c.1403G>T p.W468L | Missense Mutation (SNP) | VAF 181/443 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ADAMTS3 | c.720G>A p.Q240= | Silent (SNP) | VAF 43/874 reads (5%) | called by muse, mutect2
- ADGRD1 | c.417C>T p.S139= | Silent (SNP) | VAF 102/269 reads (38%) | catalogued as rs764811889; called by muse, mutect2, varscan2
- FAM177B | c.90C>T p.D30= | Silent (SNP) | VAF 676/1588 reads (43%) | catalogued as rs762871916, COSV62601152; called by muse, mutect2, varscan2
- LRRN4 | c.1680G>A p.A560= | Silent (SNP) | VAF 184/421 reads (44%) | catalogued as rs749574207, COSV66646642; called by muse, mutect2, varscan2
- RYR2 | c.6336C>T p.S2112= | Silent (SNP) | VAF 349/748 reads (47%) | catalogued as rs373777614; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLIT2 | c.3204C>T p.Y1068= | Silent (SNP) | VAF 54/774 reads (7%) | catalogued as rs200463383; called by muse, mutect2
- COL18A1 | c.3679-30G>A | Intron (SNP) | VAF 42/130 reads (32%) | called by mutect2, varscan2
- ERICH6B | c.1493+56C>A | Intron (SNP) | VAF 79/171 reads (46%) | called by muse, mutect2, varscan2
- GABRB3 | chr15:26773776 C>T | 5'Flank (SNP) | VAF 16/42 reads (38%) | catalogued as rs752568601; called by muse, mutect2, varscan2
- MAMLD1 | c.*97A>T | 3'UTR (SNP) | VAF 280/825 reads (34%) | called by muse, mutect2, varscan2
- MUC5AC | c.*11C>A | 3'UTR (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- PSG6 | c.706+71C>T | Intron (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- RBMX | chrX:136872320 C>T | 3'Flank (SNP) | VAF 327/883 reads (37%) | catalogued as rs1481524650; called by muse, mutect2, varscan2
